Surgical pathology report (de-identified scan), TCGA case TCGA-64-5781, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-5781-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Clinical History/Diagnosis: Lung CA

[REDACTED] TCGA-64-5781

Source of Specimen(s):

- 1: Portion of 6th Rib
- 2: 10 R Lymph Node
- 3: 11 R Lymph Node
- 4: Right upper lobe
- 5: Level 7 Lymph Node
- 6: Level 4R Lymph Node

Gross Description:

Received in six parts.

Source of Tissue: 1. Labeled #1, "portion of 6th rib"

Gross Description: Received fresh labeled, portion of 6th rib". It consists of a portion of rib measuring 1.7 x 1.5 x 0.5 cm. Representative sections submitted in 1A, following decalcification.

Source of Tissue: 2. Labeled #2, "10R lymph nodes"

Gross Description: Received fresh labeled 10R lymph nodes". It consists of two soft brown lymph nodes measuring from 1 cm up to 1.2 cm in greatest dimension. Each lymph node is bisected and entirely submitted in 2A-2B.

Source of Tissue: 3. Labeled #3, "11R lymph nodes"

Gross Description: Received fresh labeled, 11R lymph nodes". It consists of multiple black-brown soft anthracotic lymph nodes measuring from 0.2 cm up to 2 cm in greatest dimension. The lymph nodes are entirely submitted in 3A-3C.

Designation of Sections: 3A- largest lymph node bisected, 3B- one bisected lymph node, 3C- multiple additional lymph nodes

Source of Tissue: 4. Labeled #4, "right upper lobe"

Frozen Section Diagnosis: 4FS- NO TUMOR SEEN AT THE BRONCHIAL MARGIN

[REDACTED]

Gross Description: Received fresh labeled, right upper lobe". It consists of a lobe of lung weighing 223 grams and measuring 13.5 x 11.5 x 5 cm. The pleura is gray-tan and smooth except for a 2 cm gray induration noted at approximately 7 cm from the bronchial margin. The specimen is serially sectioned to reveal a 6.5 x 3.7 x 2.5 cm ill-defined firm brown mass at approximately 4.5 cm from the bronchial margin. The mass grossly corresponds to the previously described pleural induration and also comes within 0.1 cm of the closest pleura. The

[page 2 of 3]
bronchial and vascular margins are grossly unremarkable. There is a stapled margin at approximately 1.5 cm of the bronchial margin measuring 10 cm in greatest dimension. The bronchial margin is frozen in 4FS. Representative sections of the remainder of the specimen are submitted in 4A-4G.

Designation of Sections: 4FS- frozen section, 4A- vascular margin, 4B-4D- tumor with closest pleura, 4E- tumor with adjacent normal lung, 4F- stapled margin, 4G- peribronchial lymph nodes

Source of Tissue: 5. Labeled #5, "level 7 lymph nodes"

TCGA - 64 - 5781

Gross Description: Received fresh labeled ", level 7 lymph nodes". It consists of three firm brown anthracotic lymph nodes measuring from 0.7 cm up to 1.4 cm in greatest dimension. Each lymph node is bisected and entirely submitted in 5A-5C.

Source of Tissue: 6. Labeled #6, "level 4R lymph nodes"

Gross Description: Received fresh labeled, level 4R lymph nodes". It consists of a firm tan-pink lymph node measuring 1 x 1 x 0.5 cm. Also received in the same container is an additional soft yellow-tan irregular fibrofatty tissue fragment measuring 2.5 x 1 x 0.2 cm. The specimen is entirely submitted in 6A-6B.

Designation of Sections: 6A- bisected lymph node, 6B- remaining fibrofatty tissue, entirely submitted

Final Diagnosis:

1. Portion of 6th rib:

No tumor seen.

2. 10R lymph nodes:

Nine lymph nodes with no tumor seen (0/9).

3. 11R lymph nodes:

Eleven lymph nodes with no tumor seen (0/11).

4. Right lung, upper lobe:

Adenocarcinoma, WHO mixed subtype.

- The 6.5 cm poorly differentiated carcinoma does not involve the pleura surface.

- Angiolymphatic invasion is not identified.

- Surgical resection margins are free of carcinoma.

Seven peribronchial lymph nodes with no tumor seen (0/7).

5. Level 7 lymph nodes:

Seventeen lymph nodes with no tumor seen (0/17).

6. Level 4R lymph nodes:

Eight lymph nodes with no tumor seen (0/8).

[page 3 of 3]
LUNG TEMPLATE

Specimen Type
Lobectomy

TCGA-64-5781

Laterality
Right

Tumor Site
Upper lobe

Tumor Size
Greatest dimension: 6.5 cm

Histologic Type
Invasive adenocarcinoma with
Acinar Solid morphologies

Histologic Grade
Poorly differentiated

Extension of Tumor
Carcinoma does not involve visceral pleura

Venous (Large Vessel) Invasion
Absent

Arterial (Large Vessel) Invasion
Absent

Margins
Margins uninvolved by invasive carcinoma

Regional Lymph Nodes
52 regional lymph nodes examined
No regional lymph node metastasis

pTNM: T2 N0 Mx

Source: NCI Genomic Data Commons file ecf31877-5f20-4994-a1b8-169a8462ef5c (TCGA-64-5781.988A550C-800E-4BA9-9C6A-DE986969753B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).